Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A3MF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A3MF-01A (Primary Tumor).

[page 1 of 6]
100-0-3

Clinical Case Report

(For Collection of Cancerous Tissue)

Carcinoma, papillary, urothelial 8/30/3

Site: bladder, NOS C67.9

W 1/2/12

Reviewed (initials)	W 1/2/12	10/20/11

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	lower abdominal pain; fever
Symptoms:	Hematuria; weakness
Clinical Findings:	
Performance Scale (Karnofsky Score):	
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	10 (yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the U. bladder	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
U. bladder cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T3 N0 M0 Stage: III		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of tumour			
Primary Tumor			
Organ	Detailed Location	Size	
urinary bladder tumor		10 x 8 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
right bladder tumor	10 x 8 x 2 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3	No	M 0	Stage: III
Notes:			

[page 5 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		STRUCTURAL PATTERN	
Diffuse	☒	Streaming	☒
Mosaic	☒	Storiform	☒
Necrosis	☒	Fibrosis	☒
Lymphocytic Infiltration	☒	Palisading	☒
Vascular Invasion	☒	Cystic Degeneration	☒
Clusterized	☒	Bleeding	☒
Alveolar Formation	☒	Myxoid Change	☒
Indian File	☒	Pseudomoma/Calcification	☒

2. Cellular features:

Squamous	☒	Adenomatous	☒	Sarcomatous	☒	Lymphomatous	☒
Squamous Cell	☒	Glandular cell	☒	Round Cell	☒	Large Cell	☒
Spindle Cell	☒	Cell Stratification	☒	Fibroblast	☒	Small Cell	☒
Keratin	☒	Secretion	☒	Osteoblast	☒	RS Cell/RS Like	☒
Desmosome	☒	Intracyt. Vacuole	☒	Lipoblast	☒	Inflam. Cell	☒
Pearl	☒	Gland formation	☒	Myoblast	☒	Plasma Cell	☒
Otherwise Specified: D1 80%, D2 80%, D3 80%, D4 80%							

2. Cellular Differentiation:

Well	Moderately	Poor
☒	☒	☒

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis	☒	☒	☒	☒
Hyperchromatism	☒	☒	☒	☒
Nucleolar Prominent	☒	☒	☒	☒
Multinucleated Giant Cell	☒	☒	☒	☒
Mitotic Activity	☒	☒	☒	☒
Nuclear Grade	☒	☒	☒	☒

Histological Diagnosis: Papillary Transitional Cell Carcinoma, G1

Comments: _____

Date

Director, Research Pathology

[page 6 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Pallisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		☒		Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation:				Well	☒ Moderate	Poor
---------------------------	--	--	--	------	--	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell		☒		
Mitotic Activity		☒		

Nuclear Grade:			
----------------	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: primary carcinoma of the bladder
(moderately differentiated) T3N0M0, Grade: 2

Comments:

Principal Investigator

Pathologist

Date

Source: NCI Genomic Data Commons file aa0e000d-156e-44e4-95b4-df5c4c415423 (TCGA-CF-A3MF.D7C5EE9B-98F3-46C1-A568-F989E97ABFCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).